Somatic mutation profile of tumor specimen C3N-02681-02 (aliquot CPT0224870006) from CPTAC case C3N-02681, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 65.7 years (23,981 days).
Specimen C3N-02681-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69f30ada-57f5-4af7-a082-4706db3e7887.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02681-31 (Blood Derived Normal), aliquot CPT0224890002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b28b7eb0-c0d6-493e-aad2-e59ddd059092

The open-access MAF lists 84 somatic variants for this specimen: 49 protein-altering or splice-affecting, 21 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 21, Intron 10, RNA 2, 3'UTR 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 36/70 reads (51%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as rs1057519925, COSV55873816, COSV55874585; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSS3 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV54100594; called by muse, mutect2, varscan2
- ALPG | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 181/552 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs562795167, COSV54966562; called by muse, mutect2, varscan2
- CDS1 | c.1331C>T p.T444I | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.147); catalogued as rs765930064; called by muse, mutect2, varscan2
- COL6A6 | c.472G>A p.G158R | Missense Mutation (SNP) | VAF 46/209 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as rs771893072, COSV100649803, COSV62029954; called by muse, mutect2, varscan2
- DNAH14 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated, low confidence (0.23); catalogued as COSV64788651; called by muse, mutect2
- DUSP9 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 64/151 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs1557035799; called by muse, mutect2, varscan2
- GRID2IP | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 136/387 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.066); catalogued as rs952216269, COSV71849805; called by muse, mutect2, varscan2
- KCNB2 | c.1348G>T p.V450F | Missense Mutation (SNP) | VAF 62/186 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV73050540; called by muse, mutect2, varscan2
- KIF26A | c.3559C>T p.R1187* | Nonsense Mutation (SNP) | VAF 41/107 reads (38%) | catalogued as rs749490602; called by muse, mutect2, varscan2
- KRT71 | c.1384G>A p.G462S | Missense Mutation (SNP) | VAF 132/330 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs1328669270, COSV99921992; called by muse, mutect2, varscan2
- LILRB1 | c.1322C>G p.P441R (on ENST00000427581; = p.P405R on NM_006669.6) | Missense Mutation (SNP) | VAF 66/224 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100206769; called by muse, mutect2, varscan2
- NBPF4 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 77/263 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1300813973, COSV101312713; called by muse, mutect2, varscan2
- NOX1 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT tolerated (0.79); PolyPhen benign (0.041); catalogued as rs771265181, COSV54193659; called by muse, mutect2, varscan2
- PCDHA3 | c.1508C>T p.A503V | Missense Mutation (SNP) | VAF 331/919 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.426); catalogued as rs782128283, COSV63546097; called by muse, mutect2, varscan2
- RNF17 | c.3766G>A p.A1256T | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759166286, COSV55039640, COSV55041052; called by muse, mutect2, varscan2
- SHROOM2 | c.4090C>T p.R1364W | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs1318229593, COSV101098069; called by muse, mutect2, varscan2
- SLC37A4 | c.928G>A p.G310S | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.255); catalogued as CX983273; called by muse, mutect2, varscan2
- SPATA2L | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs771688020, COSV57045883; called by muse, mutect2, varscan2
- SPATA31A6 | c.1356T>A p.N452K | Missense Mutation (SNP) | VAF 24/974 reads (2%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as COSV60533140; called by muse, mutect2
- ST14 | c.1829C>T p.T610M | Missense Mutation (SNP) | VAF 97/287 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs373734230; called by muse, mutect2, varscan2
- SYT16 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 82/252 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs190756776, COSV101413659, COSV70855911; called by muse, mutect2, varscan2
- TBL1X | c.603A>T p.R201S | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV54282065; called by muse, varscan2
- TMEM132D | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 84/222 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs773830615, COSV67163159; called by muse, mutect2, varscan2
- BMP6 | c.1124C>T p.S375L | Missense Mutation (SNP) | VAF 202/560 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- BRSK1 | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 112/299 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- CACNA1F | c.848G>T p.C283F | Missense Mutation (SNP) | VAF 111/307 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFAP46 | c.5531A>T p.E1844V | Missense Mutation (SNP) | VAF 152/292 reads (52%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- CYTH4 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 57/191 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- DDX53 | c.820T>A p.L274M | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- F11R | c.875A>T p.K292I | Missense Mutation (SNP) | VAF 61/229 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- GANC | c.2609C>T p.P870L | Missense Mutation (SNP) | VAF 52/148 reads (35%) | PolyPhen benign (0.414); called by muse, mutect2, varscan2
- GFOD1 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 67/292 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HIF3A | c.152T>G p.L51R (on ENST00000377670 / NM_152795.4; = p.W31G on NM_022462.4) | Missense Mutation (SNP) | VAF 155/569 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HSF2 | c.158T>C p.F53S | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOS1 | c.3300G>T p.K1100N | Missense Mutation (SNP) | VAF 107/435 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- PHIP | c.5104A>G p.K1702E | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2
- RASAL3 | c.1557T>A p.D519E | Missense Mutation (SNP) | VAF 82/237 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RGL2 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 88/190 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SNX24 | c.200T>A p.V67D | Missense Mutation (SNP) | VAF 62/224 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- TCAIM | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- THOC2 | c.3530A>T p.K1177M | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, varscan2
- TIAM1 | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 143/468 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- TRIM24 | c.2039A>T p.H680L (on ENST00000343526 / NM_015905.3; = p.H646L on NM_003852.4) | Missense Mutation (SNP) | VAF 15/334 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); called by muse, mutect2
- TSPYL2 | c.472A>T p.R158W | Missense Mutation (SNP) | VAF 96/264 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- TYMP | c.1403C>T p.A468V | Missense Mutation (SNP) | VAF 138/380 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP9X | c.1695G>C p.W565C | Missense Mutation (SNP) | VAF 61/180 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF112 | c.1440C>G p.F480L (on ENST00000337401 / NM_001083335.2; = p.F474L on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.141); called by muse, mutect2
- ZSWIM5 | c.1520T>C p.I507T | Missense Mutation (SNP) | VAF 96/278 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ADAMTS13 | c.2922C>T p.I974= | Silent (SNP) | VAF 137/388 reads (35%) | catalogued as COSV63020195; called by muse, mutect2, varscan2
- ANKH | c.831G>A p.A277= | Silent (SNP) | VAF 177/511 reads (35%) | catalogued as rs752106674, COSV52483174, COSV52485004; called by muse, mutect2, varscan2
- C1orf167 | c.3594G>T p.R1198= | Silent (SNP) | VAF 104/376 reads (28%) | called by muse, mutect2, varscan2
- CFC1 | c.240C>T p.F80= | Silent (SNP) | VAF 121/742 reads (16%) | catalogued as rs762056382, COSV52090345, COSV52090471; called by muse, mutect2, varscan2
- DDX11 | c.705A>G p.T235= | Silent (SNP) | VAF 194/796 reads (24%) | catalogued as COSV52505823; called by muse, mutect2, varscan2
- HELZ2 | c.3240C>T p.D1080= (on ENST00000467148 / NM_001037335.2; = p.D511= on NM_033405.3) | Silent (SNP) | VAF 126/387 reads (33%) | catalogued as rs758579604, COSV64409483; called by muse, mutect2, varscan2
- HS3ST3A1 | c.1131C>T p.R377= | Silent (SNP) | VAF 48/282 reads (17%) | catalogued as COSV99404135; called by muse, mutect2
- IARS1 | c.1965A>G p.P655= | Silent (SNP) | VAF 55/158 reads (35%) | catalogued as rs1014512249; called by muse, mutect2, varscan2
- ITGAM | c.2988G>C p.S996= (on ENST00000648685 / NM_001145808.2; = p.S995= on NM_000632.4) | Silent (SNP) | VAF 79/279 reads (28%) | called by muse, mutect2, varscan2
- JAKMIP2 | c.498G>A p.V166= | Silent (SNP) | VAF 141/496 reads (28%) | catalogued as rs779647414, COSV54615219; called by muse, mutect2, varscan2
- KLK4 | c.306C>T p.S102= | Silent (SNP) | VAF 127/359 reads (35%) | catalogued as rs866842262, COSV100133585, COSV60676125; called by muse, mutect2, varscan2
- LPA | c.1203G>A p.S401= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs755484600, COSV100308288; called by mutect2, varscan2
- NLRP8 | c.2499G>A p.A833= | Silent (SNP) | VAF 59/168 reads (35%) | catalogued as rs368088277; called by muse, mutect2, varscan2
- OR2T35 | c.747C>T p.S249= | Silent (SNP) | VAF 123/458 reads (27%) | catalogued as rs770270649; called by muse, mutect2, varscan2
- OR4C5 | c.759C>T p.C253= | Silent (SNP) | VAF 98/311 reads (32%) | catalogued as rs1422713823; called by muse, mutect2, varscan2
- PCDHA2 | c.1863G>A p.P621= | Silent (SNP) | VAF 115/395 reads (29%) | catalogued as rs781990389, COSV65370686; called by muse, mutect2, varscan2
- PCDHA2 | c.2004G>A p.S668= | Silent (SNP) | VAF 106/310 reads (34%) | catalogued as rs369554786; called by muse, mutect2, varscan2
- PCDHA6 | c.1629G>A p.P543= | Silent (SNP) | VAF 353/1070 reads (33%) | catalogued as COSV65344271; called by muse, mutect2, varscan2
- PCDHGA8 | c.489C>T p.G163= | Silent (SNP) | VAF 62/192 reads (32%) | catalogued as COSV53988163; called by muse, mutect2, varscan2
- TPO | c.1653G>A p.V551= | Silent (SNP) | VAF 135/380 reads (36%) | catalogued as rs1410520809; called by muse, mutect2, varscan2
- VWA5B2 | c.1176G>A p.V392= | Silent (SNP) | VAF 66/264 reads (25%) | called by muse, mutect2, varscan2
- CERS5 | c.198-941G>A | Intron (SNP) | VAF 3/8 reads (38%) | catalogued as rs955093232; called by muse, mutect2, varscan2
- CYP2F1 | c.1294+25C>T | Intron (SNP) | VAF 93/320 reads (29%) | called by muse, mutect2, varscan2
- FAM83H | c.*35G>A | 3'UTR (SNP) | VAF 49/205 reads (24%) | catalogued as rs376024869; called by muse, mutect2, varscan2
- GRAMD1B | c.2127+80G>A | Intron (SNP) | VAF 41/246 reads (17%) | catalogued as rs992015834; called by muse, mutect2, varscan2
- HBE1 | c.-267+102469C>T | Intron (SNP) | VAF 77/197 reads (39%) | catalogued as rs773135109, COSV59673345; called by muse, mutect2, varscan2
- IRAK1 | c.137-17C>T | Intron (SNP) | VAF 39/110 reads (35%) | called by muse, mutect2, varscan2
- KLHL2 | c.26+2224T>C | Intron (SNP) | VAF 90/268 reads (34%) | called by muse, mutect2, varscan2
- LILRB5 | c.34+33G>A | Intron (SNP) | VAF 76/219 reads (35%) | catalogued as rs753167771; called by muse, mutect2, varscan2
- LINC02817 | n.405A>T | RNA (SNP) | VAF 75/210 reads (36%) | called by muse, mutect2, varscan2
- NLRP2 | c.2537+78G>A | Intron (SNP) | VAF 165/479 reads (34%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-15159G>C | Intron (SNP) | VAF 43/164 reads (26%) | called by muse, mutect2, varscan2
- SSX6P | n.392G>T | RNA (SNP) | VAF 97/296 reads (33%) | called by muse, mutect2, varscan2
- WNT7A | c.*34C>A | 3'UTR (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2, varscan2
- XPNPEP3 | c.64+3426A>C | Intron (SNP) | VAF 11/66 reads (17%) | called by muse, mutect2, varscan2
